Gene-level copy-number profile of tumor specimen ALCH-B1TR-TTP1-A from ALCHEMIST case ALCH-B1TR, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 78.0 years (28,493 days).
Specimen ALCH-B1TR-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9376953d-be85-449b-985a-3237ca798b5d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1TR-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,710 have no estimate.
https://portal.gdc.cancer.gov/files/51d7f1a6-4063-4b46-8e2c-5ecc30bdd12f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 62; copy number 1: 15,624; copy number 2: 38,841; copy number 3: 2,391; copy number 4: 1,342; copy number 5: 378; copy number 6: 58; copy number 7: 48; copy number 8: 146; copy number 9: 23.

Homozygous deletions (total copy number 0; autosomes only): 62 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:6,247,353–6,261,098, 1 gene: GPR153.
- chr1:10,639,241–10,654,333, 1 gene (within-gene range 0–1): AL139423.1.
- chr1:15,989,871–15,994,751, 1 gene: TBC1D3P6.
- chr1:16,035,178–16,040,029, 1 gene: AL355994.2.
- chr4:625,573–670,782, 3 genes (within-gene range 0–1): PDE6B, PDE6B-AS1, AC107464.2.
- chr8:22,089,150–22,104,911, 1 gene: FAM160B2.
- chr9:130,892,707–130,945,520, 3 genes: QRFP, FIBCD1, AL161733.1.
- chr13:114,107,569–114,108,820, 1 gene (within-gene range 0–1): RASA3-IT1.
- chr15:25,178,738–25,250,940, 40 genes (within-gene range 0–2): SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr16:70,661,667–70,665,836, 1 gene (within-gene range 0–1): AC020763.4.
- chr17:4,583,999–4,608,319, 1 gene: SMTNL2.
- chr17:50,525,520–50,555,852, 3 genes (within-gene range 0–2): AC021491.2, EPN3, SPATA20.
- chr22:23,059,415–23,145,021, 4 genes: RSPH14, GNAZ, Metazoa_SRP, U7.
- chr22:48,538,900–48,547,387, 1 gene (within-gene range 0–1): Z84468.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 643 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:100,562,993–101,309,534, 18 genes, copy number 6: PDCL3, HMGN2P22, LINC01849, NANOGNBP1, LINC01868, AC092168.1, NPAS2, AC092168.2, NPAS2-AS1, AC016738.1, RPL31, TBC1D8, BBIP1P1, TBC1D8-AS1, CNOT11, RNF149, SNORD89, MIR5696.
- chr3:164,670,878–184,017,939, 291 genes, copy number 5–9 (broad region; genes not listed).
- chr6:53,616,471–54,945,099, 21 genes, copy number 5 (within-gene range 3–5): LINC01564, KLHL31, AL590652.1, LRRC1, AL033384.2, MLIP, AL033384.1, MLIP-AS1, MLIP-IT1, ERHP2, AL359380.1, TINAG, TINAG-AS1, CLNS1AP1, RPL10P10, RPSAP44, KRASP1, RNU6-1023P, AL512363.1, FAM83B, AL049555.1.
- chr6:61,574,328–62,286,225, 4 genes, copy number 5: MTRNR2L9, KHDRBS2-OT1, KHDRBS2, AL355347.1.
- chr11:68,707,440–70,436,584, 52 genes, copy number 8: TESMIN, CPT1A, LINC02701, MRPL21, IGHMBP2, AP000808.1, MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr11:76,435,559–79,441,030, 67 genes, copy number 5 (broad region; genes not listed).
- chr14:36,320,753–36,656,163, 1 gene, copy number 6 (within-gene range 4–6): AL132857.1.
- chr14:36,473,207–38,371,338, 32 genes, copy number 6: SFTA3, SFTA3, NKX2-1, NKX2-1-AS1, PHKBP2, RPL29P3, NKX2-8, RN7SKP257, AL079303.1, PAX9, SLC25A21, AL162464.2, AL162464.1, MIR4503, AL079304.1, SLC25A21-AS1, RNU6-273P, MIPOL1, RNU6-886P, AL121790.2, AL121790.1, FOXA1, TTC6, AL136296.1, RNU6-1277P, LINC00517, AL359233.1, AL392023.2, AL392023.1, SSTR1, CLEC14A, AL355835.1.
- chr19:38,244,035–40,898,282, 154 genes, copy number 5–8 (within-gene range 4–8) (broad region; genes not listed).
- chr22:18,906,028–18,947,732, 3 genes, copy number 5 (within-gene range 3–5): DGCR6, AC007326.4, PRODH.

Autosomal genes at a single copy (total copy number 1): 12,796. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
